Somatic mutation profile of tumor specimen TCGA-BQ-5894-01A (aliquot TCGA-BQ-5894-01A-11D-1589-08) from TCGA case TCGA-BQ-5894, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 42.5 years (15,510 days).
Specimen TCGA-BQ-5894-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d985b817-2348-47a1-b44c-a4c6cd9cb8c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5894-11A (Solid Tissue Normal), aliquot TCGA-BQ-5894-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/970de5da-7b86-4c92-abfb-876d7b22677b

The open-access MAF lists 22 somatic variants for this specimen: 21 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 19, Frame Shift Del 1, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BUD13 | c.1007T>C p.F336S | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs754433001, COSV52769041; called by muse, mutect2, varscan2
- COL19A1 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV59570468, COSV59577886; called by muse, mutect2, varscan2
- CYTIP | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs775588319, COSV51634454; called by muse, mutect2, varscan2
- EMG1 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV54642570; called by muse, mutect2, varscan2
- FITM1 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52823537, COSV52824758; called by muse, mutect2, varscan2
- GMDS | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66416529; called by muse, mutect2, varscan2
- HECTD4 | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV61180348; called by muse, mutect2, varscan2
- ITGAL | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs199716730; called by muse, mutect2, varscan2
- KIAA2026 | c.3610A>C p.S1204R | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV67356166; called by muse, mutect2, varscan2
- KLHL31 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1294628961, COSV63882051; called by muse, mutect2, varscan2
- KLK3 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58101365; called by muse, mutect2, varscan2
- MBD5 | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV68698137; called by muse, mutect2, varscan2
- MEP1A | c.1388A>G p.E463G | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57921203; called by muse, mutect2, varscan2
- OR52N5 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV57699110; called by muse, mutect2, varscan2
- PDZD2 | c.8410A>G p.N2804D | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.975); catalogued as COSV56863536; called by muse, mutect2, varscan2
- PLXNA2 | c.1804G>T p.V602L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65442239; called by muse, mutect2, varscan2
- STAM | c.1139T>A p.M380K | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV66351666; called by muse, mutect2, varscan2
- TWNK | c.1563G>T p.M521I | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV52969673, COSV52971350; called by muse, mutect2, varscan2
- WDR45B | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66408678; called by muse, mutect2, varscan2
- DUSP12 | c.990del p.L330Ffs*17 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- KCNJ4 | c.705_706insTCC p.L235_P236insS | In Frame Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- OPN5 | c.219C>A p.I73= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV55244775, COSV55244988, COSV55246285; called by muse, mutect2, varscan2
